Surgical pathology report (de-identified scan), TCGA case TCGA-CE-A3ME, project TCGA-THCA (Thyroid Carcinoma), tissue source site ILSBio, specimen TCGA-CE-A3ME-01A (Primary Tumor).

[page 1 of 6]
M
Form Revised

Clinical Case Report

(For Collection of Cancerous Tissue)

1C8-0-3

carcinoma, papillary, thyroid 82443

Site: thyroid, NOS C73.9

W 1/2/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married		
☐ Male ☒ Female		☐ Divorced ☐ Widow	Blood Pressure	Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: Vocal change, trouble swallow
Symptoms: weight loss
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☒ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies	
	Date of Last Menses	03	
		# of Live Births	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:			02
			☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:		
Hep C	☒ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:		
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		

B/T Cell Markers:

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the lungs	
MRI		
Biopsy	Carcinoma	

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
THYROID CANCER	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T2 N0 M0 Stage: II	

Treatment Information

SURGICAL TREATMENT			
Procedure		Date of Procedure	
Resection of the tumour			
Primary Tumor			
Organ	Detailed Location	Size	
Thyroid tumor	Right thyroid tumor	4 x 3 x 2 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T2 N0 M0 Stage: II			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	0	4	0			4	0
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Thyroid Tumor	4 x 3 x 2 cm	Right thyroid	cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: II	
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			Structural Pattern			Cell Distribution			Structural Pattern		
	+	-		+	-		+	-		+	-
Diffuse		☒	Streaming								
Mosaic			Storiform								
Necrosis			Fibrosis								
Lymphocytic Infiltration			Palisading								
Vascular Invasion		☒	Cystic Degeneration								
Clusterized			Bleeding								
Alveolar Formation			Myxoid Change								
Indian File			Psammoma/Calcification								

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell		☒	Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation:	Well	Moderate	Poor
---------------------------	------	----------	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism		☒		
Nucleolar Prominent		☒		
Multinucleated Giant Cell		☒		
Mitotic Activity		☒		

Nuclear Grade:				
----------------	--	--	--	--

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: papillary carcinoma of the thyroid
pT2N0M0, Stage II Grade:

Comments:

Principal Investigator

Pathologist

ate

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Otherwise Specified:

D1 50%, D2 70%, D3 60%, D4 70%

2. Cellular Differentiation:

Well	Moderately	Poor
X		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism		X		
Nucleolar Prominent		X		
Multinucleated Giant Cell		X		
Mitotic Activity		X		
Nuclear Grade				

Histological Diagnosis: Papillary Thyroid Carcinoma, G1

Comments: _____

Date: _____

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file bf2cb0eb-dfa5-4252-a251-8a90a97de3b8 (TCGA-CE-A3ME.F252CA7B-53A5-44A2-BABC-37EF371C1619.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).